TCGA case TCGA-L5-A43I — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus; Tissue source site: University of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/22ee75e0-5d61-41f4-aacd-b4e09c70d2c3

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 77 years; Vital status: Dead; Days to death: 556 days (1.5 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 77.7 years (28,367 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 556 days (1.5 years); Cancer detection method: Symptomatic; Esophageal columnar dysplasia degree: High Grade Dysplasia; Esophageal columnar metaplasia present: Yes; Goblet cells columnar mucosa present: No; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Negative; Lymph nodes positive: 2; Lymph nodes tested: 10.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
2. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Blood; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Warfarin Sodium; Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (1 entry)
- Days to follow up: 556 days (1.5 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 121 kg; Height: 172 cm; BMI: 40.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 45.
- Alcohol history: Yes; Alcohol drinks per day: 2; Alcohol days per week: 7.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-L5-A43I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 340 mg.
  Slide TCGA-L5-A43I-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 6; Percent neutrophil infiltration: 0.
- Sample TCGA-L5-A43I-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 170 mg.
  Slide TCGA-L5-A43I-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Cancer procurement state province: MI; Cancer procurement city: Ann Arbor; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 7; History barretts esophageal indicator: No; New tumor event diagnosis indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Adenocarcinoma, NOS; Lymph node sprd radiograph evidence: No; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Blood.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form, Drug treatment, Administered drug: Pharmaceutical therapy drug name: coumadin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 556 days; disease-specific survival: no event (censored), 556 days; disease-free interval: no event (censored), 556 days; progression-free interval: no event (censored), 556 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-L5-A43I-01A-11D-A246-01): tumor purity 0.67, ploidy 3.11, whole-genome doublings 1.
